Gene-level copy-number profile of tumor specimen ALCH-B3L4-TTP1-A from ALCHEMIST case ALCH-B3L4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.9 years (19,315 days).
Specimen ALCH-B3L4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cae935dd-ebc2-49e5-b4bf-dcbdc90ec656.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3L4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/b93f6d46-33af-4741-aca8-5e12860df8bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 556; copy number 1: 18,126; copy number 2: 36,073; copy number 3: 3,281; copy number 4: 459; copy number 5: 269; copy number 6: 50; copy number 7: 43; copy number 9: 29; copy number 18: 8; copy number 19: 14.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:923,928–959,309, 2 genes: SAMD11, NOC2L.
- chr2:231,711,525–231,711,647, 1 gene (within-gene range 0–1): U4.
- chr7:1,074,450–1,093,815, 3 genes (within-gene range 0–1): AC091729.1, AC091729.2, GPER1.
- chr7:2,234,195–2,251,146, 2 genes: MRM2, NUDT1.
- chr7:2,257,515–2,257,577, 1 gene (within-gene range 0–1): MIR6836.
- chr7:2,512,529–2,529,177, 2 genes: LFNG, MIR4648.
- chr8:12,362,019–12,400,366, 4 genes: FAM66A, AC087203.1, AC087203.2, DEFB109A.
- chr9:124,262,876–124,265,809, 1 gene (within-gene range 0–2): AL162724.1.
- chr11:65,615,773–65,637,439, 2 genes (within-gene range 0–1): PCNX3, MIR4690.
- chr16:4,748,239–4,767,624, 2 genes (within-gene range 0–2): ZNF500, Metazoa_SRP.
- chr18:79,576,460–79,589,010, 1 gene: AC068473.3.
- chr19:3,958,453–3,985,463, 4 genes (within-gene range 0–2): DAPK3, MIR637, EEF2, SNORD37.
- chr19:49,047,638–49,058,860, 3 genes (within-gene range 0–3): CGB8, AC008687.6, CGB7.
- chr19:49,056,088–49,058,761, 1 gene (within-gene range 0–3): AC008687.7.
- chr20:63,939,829–63,956,416, 3 genes (within-gene range 0–1): UCKL1, MIR1914, MIR647.
- chr22:17,734,138–17,779,481, 3 genes: BID, MIR3198-1, LINC00528.
- chr22:17,787,652–17,811,497, 2 genes (within-gene range 0–1): AC016026.1, AC016026.2.
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.
- chr22:20,198,729–20,208,524, 2 genes: AC007663.2, LINC00896.
- chr22:41,229,510–41,286,187, 3 genes (within-gene range 0–1): CHADL, RANGAP1, MIR6889.
- chr22:48,538,900–48,547,387, 1 gene (within-gene range 0–1): Z84468.1.
- chr22:50,445,000–50,475,035, 1 gene (within-gene range 0–1): SBF1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 413 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,874,793–143,883,575, 1 gene, copy number 5 (within-gene range 5–6): FCGR1CP.
- chr8:34,784,028–38,601,200, 76 genes, copy number 6–9 (broad region; genes not listed).
- chr9:41,700,480–41,701,096, 2 genes, copy number 7: AL591926.1, AL591926.4.
- chr11:68,460,731–68,615,334, 1 gene, copy number 7 (within-gene range 2–7): PPP6R3.
- chr11:68,612,899–79,441,030, 329 genes, copy number 5–19 (within-gene range 2–19) (broad region; genes not listed).
- chr14:105,583,731–105,588,395, 1 gene, copy number 6: IGHA2.
- chr21:44,107,373–44,131,181, 1 gene, copy number 18: PWP2.
- chr21:44,172,169–44,194,338, 2 genes, copy number 9: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 15,782. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
